Somatic mutation profile of tumor specimen HCM-CSHL-0664-C18-06A (aliquot HCM-CSHL-0664-C18-06A-11D-A85K-36) from HCMI case HCM-CSHL-0664-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.4 years (22,442 days).
Specimen HCM-CSHL-0664-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe1391d4-9f9b-42fc-bed7-c96386f0d0e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0664-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0664-C18-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/739b3f4a-5ce4-47db-a09e-3b3b67db0179

The open-access MAF lists 306 somatic variants for this specimen: 233 protein-altering or splice-affecting, 61 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 61, Nonsense Mutation 9, Frame Shift Del 7, Intron 5, Frame Shift Ins 3, In Frame Del 2, RNA 2, 3'UTR 2, 3'Flank 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 143/176 reads (81%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 82/270 reads (30%) | catalogued as rs964532159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 183/231 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA9 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV60632758; called by muse, mutect2, varscan2
- ABCC3 | c.3964G>A p.V1322M | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs142763506; called by muse, varscan2
- ACTL7B | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 127/430 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs146150612; called by muse, mutect2, varscan2
- ANK2 | c.8988A>C p.E2996D | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV52153754; called by mutect2, varscan2
- ATG13 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 148/359 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1442396941, COSV56317472; called by muse, mutect2, varscan2
- ATP13A1 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365610; called by muse, mutect2, varscan2
- ATXN7L1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 204/339 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as rs1015081086; called by muse, mutect2, varscan2
- BBS2 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs954885169; called by muse, mutect2, varscan2
- C18orf63 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs533857307; called by muse, mutect2, varscan2
- CALD1 | c.1597G>A p.G533S (on ENST00000361675 / NM_033138.4; = p.G278S on NM_004342.7) | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs768053736; called by muse, mutect2, varscan2
- CC2D1A | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs368857635, COSV58782756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 94/379 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs151149068; called by muse, mutect2, varscan2
- CD8A | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1200297621; called by muse, mutect2, varscan2
- CEP295 | c.6965G>C p.R2322P | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs369506006; called by muse, mutect2, varscan2
- CLEC4G | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1250842245; called by muse, mutect2, varscan2
- COL16A1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs771126348; called by muse, mutect2, varscan2
- COL7A1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 107/508 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as rs201557549, COSV100097637; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2, varscan2
- CSMD3 | c.8872G>T p.V2958L (on ENST00000297405 / NM_001363185.1; = p.V2789L on NM_052900.3) | Missense Mutation (SNP) | VAF 72/844 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99839667; called by muse, mutect2
- CUL5 | c.381del p.K127Nfs*25 | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | catalogued as COSV67609527; called by mutect2, pindel, varscan2
- CWC22 | c.2630G>C p.R877T | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1001068433; called by muse, mutect2, varscan2
- DAAM2 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 82/813 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs564327973, COSV99226717; called by muse, mutect2, varscan2
- DCLK1 | c.2200C>T p.R734C (on ENST00000360631 / NM_001330072.2; = p.R427C on NM_001195416.2) | Missense Mutation (SNP) | VAF 126/340 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs745824879, COSV55184046; called by muse, mutect2, varscan2
- DEPDC1B | c.1306A>G p.S436G | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs768195193; called by muse, mutect2, varscan2
- DLGAP4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 130/1198 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762577016, COSV59422245; called by muse, varscan2
- EHD2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 172/380 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs775528505, COSV99621841; called by muse, mutect2, varscan2
- EHMT2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 274/321 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs150258444; called by muse, mutect2, varscan2
- EIF5A2 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.912); catalogued as rs1219324852, COSV55542460; called by muse, mutect2, varscan2
- FAM124A | c.268C>T p.R90W (on ENST00000322475 / NM_001242312.2; = p.R126W on NM_145019.4) | Missense Mutation (SNP) | VAF 99/464 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs775685213, COSV54474785; called by muse, mutect2, varscan2
- FAM135A | c.710C>T p.A237V (on ENST00000370479 / NM_001351599.1; = p.A194V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1232670943, COSV99525885; called by muse, mutect2, varscan2
- FAM162B | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 24/167 reads (14%) | catalogued as rs1285677851; called by muse, mutect2, varscan2
- FAM47A | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 269/307 reads (88%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs373238471; ClinVar: benign; called by muse, mutect2, varscan2
- FAM50B | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as rs755628628; called by muse, mutect2, varscan2
- FAM89B | c.211_237del p.A71_G79del | In Frame Del (DEL) | VAF 162/528 reads (31%) | catalogued as rs1458727275; called by mutect2, pindel, varscan2
- FAT3 | c.4012C>A p.Q1338K | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV53171489; called by muse, mutect2, varscan2
- FCHSD2 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1268529129; called by muse, mutect2, varscan2
- FES | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 97/132 reads (73%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764321716, COSV100183285, COSV60997644; called by muse, mutect2, varscan2
- FGF19 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 167/402 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99594276; called by muse, mutect2, varscan2
- FTSJ3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs200565432; called by muse, mutect2, varscan2
- G6PC | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768385469, COSV53830027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GP1BA | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 162/208 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs372575136; called by muse, varscan2
- HAAO | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 260/291 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54310738; called by muse, mutect2
- HACD4 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 91/163 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101529970, COSV72136707; called by muse, mutect2, varscan2
- HECW1 | c.3897C>G p.F1299L | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV67828547, COSV67835858; called by muse, mutect2
- HSP90AB1 | c.1655A>T p.K552M | Missense Mutation (SNP) | VAF 88/659 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs756933263, COSV100806874; called by muse, mutect2, varscan2
- INSRR | c.2711G>C p.S904T | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs761505447; called by muse, mutect2, varscan2
- KCNB1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 118/1223 reads (10%) | catalogued as COSV65568337; called by muse, mutect2
- KCND2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 219/378 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1355394284, COSV58570790; called by muse, mutect2, varscan2
- KRT31 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 252/628 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs748743219, COSV52435034; called by muse, mutect2, varscan2
- LRFN5 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 172/437 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1476091978; called by muse, mutect2, varscan2
- MCU | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 93/167 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs770146478, COSV64068211; called by muse, mutect2, varscan2
- MEFV | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 53/679 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99560193; called by muse, mutect2
- MSC | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 126/1177 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100335583; called by muse, mutect2, varscan2
- MUC17 | c.11951C>G p.S3984C | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV60296749; called by muse, mutect2, varscan2
- MYO6 | c.3544C>T p.R1182C (on ENST00000369981; = p.R1172C on NM_004999.4) | Missense Mutation (SNP) | VAF 146/402 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752568854; called by muse, mutect2, varscan2
- NELFA | c.940G>A p.G314S (on ENST00000542778; = p.G303S on NM_005663.5) | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1209464280, COSV100373049; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 207/452 reads (46%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- NPSR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 138/382 reads (36%) | catalogued as rs201063902, COSV62202036; called by muse, mutect2, varscan2
- NR5A1 | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146454575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLA1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 154/234 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs549904049, COSV99034477; called by muse, mutect2, varscan2
- OR5P3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 102/696 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60429326; called by mutect2, varscan2
- OTOA | c.1591G>A p.E531K (on ENST00000286149; = p.E517K on NM_144672.4) | Missense Mutation (SNP) | VAF 139/367 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760392364; called by muse, mutect2, varscan2
- PDE1B | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs558733078, COSV54492626; called by muse, mutect2, varscan2
- PHF3 | c.5116A>T p.K1706* | Nonsense Mutation (SNP) | VAF 57/276 reads (21%) | catalogued as COSV100013330; called by muse, mutect2, varscan2
- PKD1 | c.7802G>T p.R2601L | Missense Mutation (SNP) | VAF 114/481 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51925820; called by muse, mutect2, varscan2
- PKHD1L1 | c.4682C>T p.S1561L | Missense Mutation (SNP) | VAF 26/970 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV65740472; called by muse, mutect2
- PLEKHG4B | c.3805C>T p.R1269C (on ENST00000283426; = p.R1625C on NM_052909.5) | Missense Mutation (SNP) | VAF 195/473 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.042); catalogued as rs115163479, COSV52055777; called by muse, mutect2, varscan2
- PNMA6E | c.1627G>A p.A543T (on ENST00000445091 / NM_001367770.1; = p.A265T on NM_001351293.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 255/292 reads (87%) | SIFT tolerated (0.43); PolyPhen benign (0.199); catalogued as rs1471163759; called by muse, mutect2, varscan2
- PRKN | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs552077922, COSV58229750; called by muse, mutect2, varscan2
- PTCHD4 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 107/883 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV59786302; called by muse, mutect2, varscan2
- PTH2R | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 179/403 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553009188, COSV99782945; called by muse, mutect2, varscan2
- PTPN7 | c.889C>T p.R297W (on ENST00000495688; = p.R336W on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776477209; called by muse, mutect2, varscan2
- RELB | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); catalogued as rs55723886, COSV55508191; called by muse, mutect2, varscan2
- RNF5 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770949300; called by muse, mutect2, varscan2
- RSF1 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs777680460, COSV57837035; called by muse, mutect2
- RTBDN | c.215C>T p.P72L (on ENST00000393233 / NM_001270444.1; = p.P104L on NM_031429.2) | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1409582576; called by muse, mutect2, varscan2
- RYR3 | c.10063C>T p.R3355W (on ENST00000389232; = p.R3356W on NM_001036.6) | Missense Mutation (SNP) | VAF 143/189 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755340876, COSV66805329; called by muse, mutect2, varscan2
- SBNO1 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as rs1225016162; called by muse, mutect2, varscan2
- SCUBE2 | c.2372C>A p.T791N (on ENST00000649792 / NM_001367977.2; = p.T734N on NM_020974.3) | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757922583; called by muse, mutect2, varscan2
- SEC11C | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 140/187 reads (75%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs753497341, COSV55312414; called by muse, mutect2, varscan2
- SEC24B | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 119/214 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.679); catalogued as rs372703752; called by muse, mutect2, varscan2
- SECISBP2 | c.923T>A p.L308* | Nonsense Mutation (SNP) | VAF 129/229 reads (56%) | catalogued as COSV60529167; called by muse, mutect2, varscan2
- SFMBT2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752198642, COSV62813928; called by muse, mutect2, varscan2
- SIM1 | c.850+1G>A p.X284_splice | Splice Site (SNP) | VAF 130/239 reads (54%) | catalogued as COSV99492013; called by muse, mutect2, varscan2
- SLCO6A1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 211/341 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV101134332; called by muse, mutect2, varscan2
- SOX17 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 163/1450 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs746536924, COSV52028884; called by muse, mutect2, varscan2
- SPAG17 | c.5053G>C p.G1685R | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100308475; called by muse, mutect2, varscan2
- SPATA18 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs1560583856; called by muse, mutect2, varscan2
- SPIN1 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 149/271 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV65498609; called by muse, mutect2, varscan2
- SPPL2C | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 310/617 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1248867414, COSV61292647; called by muse, mutect2, varscan2
- SYPL2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 99/194 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200417619, COSV63995343; called by muse, mutect2, varscan2
- TAF1L | c.3213G>T p.R1071S | Missense Mutation (SNP) | VAF 148/546 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV54264064; called by muse, mutect2, varscan2
- TECTA | c.6229G>T p.V2077L | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs761205056; called by muse, mutect2, varscan2
- TGIF2LY | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 87/131 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs367841917, COSV100339616; called by muse, mutect2, varscan2
- THOP1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs981153307, COSV57017969; called by muse, mutect2, varscan2
- TNFRSF4 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55417567; called by muse, mutect2, varscan2
- TNNT2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 69/294 reads (23%) | catalogued as COSV52663416; called by muse, mutect2, varscan2
- TOGARAM2 | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201189267, COSV65421368; called by muse, mutect2, varscan2
- TRIM49C | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs780192949, COSV71510513; called by muse, mutect2, varscan2
- TRPV1 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 204/270 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780970901; called by muse, mutect2, varscan2
- UPB1 | c.937T>A p.F313I | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58116373; called by muse, mutect2, varscan2
- USH2A | c.9205C>T p.P3069S | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as rs1428395974; called by muse, mutect2, varscan2
- WDR64 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs979493230; called by muse, mutect2
- XYLT1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs192917273, COSV54485773; called by muse, mutect2, varscan2
- ZCCHC13 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 263/304 reads (87%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV100272496, COSV59866426; called by muse, mutect2, varscan2
- ZNF337 | c.1823G>C p.G608A | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1412992393; called by muse, mutect2, varscan2
- ZNF433 | c.1582C>G p.H528D | Missense Mutation (SNP) | VAF 104/462 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100795031; called by muse, mutect2, varscan2
- ZNF679 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV55381661; called by muse, mutect2, varscan2
- ZNF91 | c.3029C>G p.T1010S | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.61); catalogued as rs746987256; called by muse, mutect2, varscan2
- ABCA7 | c.2110C>G p.L704V | Missense Mutation (SNP) | VAF 118/514 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ABHD17B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ACAN | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 179/222 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM8 | c.1007T>G p.M336R | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADGRL2 | c.1755_1756insC p.D586Rfs*8 | Frame Shift Ins (INS) | VAF 64/246 reads (26%) | called by mutect2, pindel, varscan2
- AFG1L | c.1363T>G p.F455V | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, varscan2
- AFG1L | c.1364T>A p.F455Y | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- AHRR | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 146/643 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- AKAP8L | c.1208A>T p.E403V | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- AMBN | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANGPT1 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 67/865 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ANKRD16 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 282/586 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AP3B2 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- APBB1IP | c.1269_1270del p.Y424* | Frame Shift Del (DEL) | VAF 84/282 reads (30%) | called by pindel, varscan2
- ARPC2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ASPM | c.8724G>T p.Q2908H | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BAP1 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 174/442 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BFSP1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CABP1 | c.608C>A p.P203Q | Missense Mutation (SNP) | VAF 178/311 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CACHD1 | c.3212A>T p.K1071I | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACHD1 | c.3213A>T p.K1071N | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCNB3 | c.2716A>G p.K906E | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CENPA | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CFAP100 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRDL1 | c.328G>A p.E110K (on ENST00000372045; = p.E116K on NM_145234.4) | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CLIC6 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 156/730 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGB1 | c.3158A>T p.N1053I | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNOT1 | c.3229A>G p.T1077A | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COMTD1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 114/348 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRYBG3 | c.5014del p.Q1672Kfs*14 | Frame Shift Del (DEL) | VAF 64/314 reads (20%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5519T>C p.L1840P (on ENST00000297405 / NM_001363185.1; = p.L1736P on NM_052900.3) | Missense Mutation (SNP) | VAF 49/632 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- CYP2C18 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP7B1 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 112/623 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- DAZ4 | c.1007A>C p.Y336S (on ENST00000382296; = p.Y171S on NM_020420.3) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DHX9 | c.1098T>G p.N366K | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- DND1 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 297/351 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DYRK4 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- EIF2A | c.1692G>C p.Q564H | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERBB2 | c.2401A>T p.M801L | Missense Mutation (SNP) | VAF 98/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERG | c.663C>G p.N221K | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ERI2 | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM91A1 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 90/570 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMO1 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FRYL | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 48/181 reads (27%) | called by muse, mutect2, varscan2
- FSIP2 | c.2770A>G p.R924G | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GCNT1 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 197/338 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPAA1 | c.178_191del p.V60Cfs*29 | Frame Shift Del (DEL) | VAF 124/1256 reads (10%) | called by mutect2, pindel
- HYDIN | c.10085T>A p.V3362D | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- IGF1R | c.3246G>A p.M1082I | Missense Mutation (SNP) | VAF 140/186 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG3 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 202/537 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ITGA10 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ITGA6 | c.2848G>A p.D950N (on ENST00000442250; = p.D911N on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF4B | c.3050C>A p.S1017Y | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- KRTAP5-5 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 111/637 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LILRB2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 129/568 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, varscan2
- LRP11 | c.1258A>T p.S420C | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MAP2 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by mutect2, varscan2
- MBOAT7 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 118/479 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGST3 | c.443C>G p.P148R | Missense Mutation (SNP) | VAF 125/224 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSRB2 | c.547T>C p.*183Rext*24 | Nonstop Mutation (SNP) | VAF 194/327 reads (59%) | called by muse, mutect2, varscan2
- MUC22 | c.3569_3570insGGAAGGCTCTGAGACCACCACAGCCTCTAC p.T1185_E1194dup | In Frame Ins (INS) | VAF 81/693 reads (12%) | called by muse*, mutect2
- MUCL1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- MYBL1 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 40/622 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- NAA15 | c.2412G>C p.E804D | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAT8 | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NBEA | c.3407A>C p.K1136T | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NBEA | c.6316G>C p.D2106H | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- NCLN | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK7 | c.257T>A p.L86H | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOX5 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPVF | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 144/393 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NSD3 | c.1223dup p.S409Efs*9 | Frame Shift Ins (INS) | VAF 163/717 reads (23%) | called by mutect2, pindel, varscan2
- OR10AC1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OR10J4 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 164/291 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2H1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 120/617 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OSR2 | c.36_37insT p.H13Sfs*105 | Frame Shift Ins (INS) | VAF 154/1472 reads (10%) | called by mutect2, pindel, varscan2
- PCLO | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PEAK3 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 207/446 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PLEKHA7 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 253/437 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PLXNA2 | c.620_621del p.P207Rfs*9 | Frame Shift Del (DEL) | VAF 55/337 reads (16%) | called by mutect2, pindel, varscan2
- PLXNC1 | c.3576G>T p.Q1192H | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PPIC | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRUNE2 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPRB | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PTPRN | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTPRQ | c.4718C>T p.T1573I (on ENST00000616559; = p.T1531I on NM_001145026.2) | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RALGAPA2 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAPH1 | c.3713C>A p.P1238H | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM15 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RD3L | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- RELN | c.5104G>A p.V1702I | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIC3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 78/591 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RP1 | c.5431C>T p.P1811S | Missense Mutation (SNP) | VAF 69/624 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RTCB | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDF4 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 131/446 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SH3D19 | c.1007A>C p.Q336P | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SLC15A2 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC25A34 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 90/504 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- SNX17 | c.635A>C p.D212A | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPAG1 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 58/761 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPATA31E1 | c.3493C>A p.Q1165K | Missense Mutation (SNP) | VAF 183/371 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SPRR4 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SSR3 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SYNE2 | c.5077del p.T1693Lfs*32 | Frame Shift Del (DEL) | VAF 56/286 reads (20%) | called by mutect2, pindel, varscan2
- SZT2 | c.8479C>G p.P2827A (on ENST00000634258 / NM_001365999.1; = p.P2770A on NM_015284.4) | Missense Mutation (SNP) | VAF 178/320 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TEKT3 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TFDP1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TLL1 | c.2318A>T p.E773V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132B | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 192/345 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC6A | c.99_100del p.K35Rfs*15 | Frame Shift Del (DEL) | VAF 44/270 reads (16%) | called by pindel, varscan2
- TOP3B | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by mutect2, varscan2
- TRPT1 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- UNC80 | c.8071G>C p.D2691H | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USF3 | c.4597_4623del p.T1533_K1541del | In Frame Del (DEL) | VAF 94/494 reads (19%) | called by mutect2, pindel
- USH2A | c.11154T>G p.S3718R | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 57/578 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2
- WWP1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- XRCC5 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 254/288 reads (88%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZNF717 | c.2643G>C p.Q881H | Missense Mutation (SNP) | VAF 169/494 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF804A | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 24/465 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- ADCY2 | c.2982C>T p.D994= | Silent (SNP) | VAF 54/474 reads (11%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2904G>A p.L968= (on ENST00000311519 / NM_001145168.1; = p.L769= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/379 reads (21%) | catalogued as rs774317223; called by muse, mutect2, varscan2
- AMIGO3 | c.318C>G p.V106= | Silent (SNP) | VAF 125/476 reads (26%) | called by muse, mutect2, varscan2
- ANKH | c.183C>T p.F61= | Silent (SNP) | VAF 123/801 reads (15%) | catalogued as COSV99414815; called by muse, mutect2, varscan2
- ATP5F1E | c.114T>C p.T38= | Silent (SNP) | VAF 52/484 reads (11%) | catalogued as rs374383553; ClinVar: likely benign; called by muse, mutect2, varscan2
- C11orf96 | c.1008G>A p.V336= (on ENST00000339446; = p.V23= on NM_001145033.2) | Silent (SNP) | VAF 221/497 reads (44%) | called by muse, mutect2, varscan2
- CDH8 | c.1830C>T p.V610= | Silent (SNP) | VAF 98/465 reads (21%) | catalogued as rs766269925, COSV54883946; called by muse, mutect2, varscan2
- CHAMP1 | c.2256C>T p.L752= | Silent (SNP) | VAF 167/372 reads (45%) | called by muse, mutect2, varscan2
- CNGB1 | c.3159C>T p.N1053= | Silent (SNP) | VAF 74/365 reads (20%) | called by muse, mutect2, varscan2
- CXCR2 | c.303G>A p.L101= | Silent (SNP) | VAF 97/487 reads (20%) | catalogued as COSV59279877; called by muse, mutect2, varscan2
- DDX56 | c.342A>T p.R114= | Silent (SNP) | VAF 73/393 reads (19%) | called by muse, mutect2, varscan2
- DDX60 | c.1989G>A p.T663= | Silent (SNP) | VAF 18/259 reads (7%) | catalogued as rs745578311, COSV67095797; called by muse, mutect2
- DOT1L | c.2301C>T p.A767= | Silent (SNP) | VAF 225/522 reads (43%) | catalogued as rs573382419; called by muse, mutect2, varscan2
- EPB41L4B | c.2451G>C p.P817= | Silent (SNP) | VAF 66/261 reads (25%) | called by muse, mutect2
- EPHA10 | c.2469C>T p.F823= | Silent (SNP) | VAF 19/388 reads (5%) | catalogued as COSV57621366; called by muse, mutect2
- EPHB1 | c.1051C>A p.R351= | Silent (SNP) | VAF 92/423 reads (22%) | catalogued as COSV67665911; called by muse, mutect2, varscan2
- EXO1 | c.174T>C p.F58= | Silent (SNP) | VAF 93/155 reads (60%) | catalogued as COSV100799614; called by muse, mutect2, varscan2
- FUS | c.687T>C p.G229= | Silent (SNP) | VAF 209/596 reads (35%) | catalogued as rs781445592, COSV54217802; ClinVar: likely benign; called by mutect2, varscan2
- GALNT7 | c.1620C>T p.F540= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs781093537; called by muse, mutect2, varscan2
- GCNT7 | c.828G>A p.R276= | Silent (SNP) | VAF 153/825 reads (19%) | called by muse, mutect2, varscan2
- GLS | c.489C>G p.L163= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs1205775896, COSV57845317; called by muse, mutect2, varscan2
- HAT1 | c.942G>A p.V314= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as rs1026684461; called by muse, mutect2, varscan2
- HGF | c.540T>A p.P180= | Silent (SNP) | VAF 69/261 reads (26%) | called by muse, mutect2, varscan2
- IKZF1 | c.1212C>T p.N404= | Silent (SNP) | VAF 112/543 reads (21%) | catalogued as COSV58782083; called by muse, mutect2, varscan2
- KAT5 | c.1086G>A p.T362= | Silent (SNP) | VAF 155/354 reads (44%) | catalogued as rs775816226; called by muse, mutect2, varscan2
- KLF8 | c.310C>T p.L104= | Silent (SNP) | VAF 121/286 reads (42%) | catalogued as COSV63847830; called by muse, mutect2, varscan2
- LAMA4 | c.3639T>C p.N1213= (on ENST00000230538 / NM_001105206.3; = p.N1206= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 129/329 reads (39%) | called by muse, mutect2, varscan2
- MYH11 | c.4899C>T p.A1633= | Silent (SNP) | VAF 83/492 reads (17%) | catalogued as rs760584464, COSV100259841, COSV55552723; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.816T>C p.Y272= | Silent (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- NLGN4Y | c.2187C>A p.I729= | Silent (SNP) | VAF 96/108 reads (89%) | catalogued as COSV100196868; called by muse, mutect2, varscan2
- NTN4 | c.738A>G p.Q246= | Silent (SNP) | VAF 83/299 reads (28%) | called by muse, mutect2, varscan2
- OR4Q3 | c.348A>G p.L116= | Silent (SNP) | VAF 130/479 reads (27%) | called by muse, mutect2, varscan2
- OR52N4 | c.705T>G p.A235= | Silent (SNP) | VAF 91/613 reads (15%) | called by muse, mutect2, varscan2
- PCDH18 | c.2086T>C p.L696= | Silent (SNP) | VAF 71/274 reads (26%) | catalogued as rs779292769; called by muse, mutect2, varscan2
- PCDH8 | c.405C>T p.F135= | Silent (SNP) | VAF 119/537 reads (22%) | called by muse, mutect2, varscan2
- PKHD1 | c.9057T>A p.T3019= | Silent (SNP) | VAF 460/652 reads (71%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.10653T>C p.T3551= | Silent (SNP) | VAF 24/902 reads (3%) | called by muse, mutect2
- PLOD2 | c.528C>G p.V176= | Silent (SNP) | VAF 56/282 reads (20%) | catalogued as rs758503433; called by muse, mutect2, varscan2
- PNMT | c.717G>A p.V239= | Silent (SNP) | VAF 102/465 reads (22%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.928T>C p.L310= | Silent (SNP) | VAF 82/310 reads (26%) | catalogued as COSV53576618; called by muse, mutect2, varscan2
- PRKCB | c.1422C>T p.L474= | Silent (SNP) | VAF 138/316 reads (44%) | catalogued as rs771588066, COSV57799403; called by muse, mutect2, varscan2
- RYR2 | c.4752G>A p.P1584= | Silent (SNP) | VAF 191/344 reads (56%) | catalogued as rs780111656, COSV63658984; ClinVar: uncertain significance; called by muse, varscan2
- SALL4 | c.951G>A p.P317= | Silent (SNP) | VAF 54/1062 reads (5%) | catalogued as rs766412152, COSV53849654, COSV99409650; called by muse, mutect2
- SBNO2 | c.984C>T p.I328= | Silent (SNP) | VAF 16/420 reads (4%) | catalogued as rs1365974089, COSV62323069; called by muse, mutect2
- SHC3 | c.1494T>G p.T498= | Silent (SNP) | VAF 122/382 reads (32%) | called by muse, mutect2, varscan2
- SI | c.2805C>T p.F935= | Silent (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- SLC32A1 | c.75C>T p.S25= | Silent (SNP) | VAF 111/995 reads (11%) | catalogued as COSV54145603; called by muse, mutect2, varscan2
- SOX3 | c.915C>T p.A305= | Silent (SNP) | VAF 117/269 reads (43%) | catalogued as rs755200355; called by muse, varscan2
- SYNE2 | c.16563T>C p.D5521= | Silent (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- TDRD6 | c.168G>T p.T56= | Silent (SNP) | VAF 102/969 reads (11%) | catalogued as COSV100288283; called by muse, mutect2, varscan2
- THBD | c.1077C>T p.D359= | Silent (SNP) | VAF 108/696 reads (16%) | catalogued as COSV65702899; called by muse, mutect2, varscan2
- TLE6 | c.426G>A p.P142= (on ENST00000246112 / NM_001143986.2; = p.P19= on NM_024760.3) | Silent (SNP) | VAF 185/415 reads (45%) | catalogued as rs757907159, COSV99858315; called by muse, mutect2, varscan2
- TMEM106A | c.363G>T p.V121= | Silent (SNP) | VAF 90/471 reads (19%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1443G>C p.T481= | Silent (SNP) | VAF 50/224 reads (22%) | catalogued as rs771245667; called by muse, mutect2, varscan2
- TRIM50 | c.798C>A p.I266= | Silent (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- VIL1 | c.714G>C p.A238= | Silent (SNP) | VAF 355/552 reads (64%) | catalogued as rs201560572; called by muse, mutect2, varscan2
- VNN2 | c.1146C>T p.Y382= | Silent (SNP) | VAF 59/337 reads (18%) | catalogued as rs528212065; called by muse, mutect2, varscan2
- WASHC2C | c.1077C>A p.G359= | Silent (SNP) | VAF 70/366 reads (19%) | called by muse, mutect2, varscan2
- WDR64 | c.1662C>T p.L554= | Silent (SNP) | VAF 89/309 reads (29%) | called by muse, mutect2, varscan2
- XPO4 | c.3192A>G p.Q1064= | Silent (SNP) | VAF 170/414 reads (41%) | catalogued as rs1189758355; called by muse, mutect2, varscan2
- ZNF676 | c.1776C>A p.P592= (on ENST00000650058; = p.P560= on NM_001001411.3) | Silent (SNP) | VAF 86/401 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1200+140C>G | Intron (SNP) | VAF 101/433 reads (23%) | catalogued as COSV99770768; called by muse, mutect2, varscan2
- CCDC158 | c.1029+3596A>G | Intron (SNP) | VAF 74/244 reads (30%) | called by muse, mutect2, varscan2
- DUSP13 | c.*308-1474C>A | Intron (SNP) | VAF 130/274 reads (47%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32790A>C | Intron (SNP) | VAF 113/394 reads (29%) | called by muse, mutect2, varscan2
- KCNQ2 | c.*5942G>A | 3'UTR (SNP) | VAF 114/1172 reads (10%) | catalogued as rs1327847651; called by muse, mutect2
- LINC00960 | chr3:75678897 C>T | 3'Flank (SNP) | VAF 85/379 reads (22%) | catalogued as rs1410195668; called by muse, mutect2, varscan2
- LINP1 | n.375G>A | RNA (SNP) | VAF 276/439 reads (63%) | catalogued as rs1021600801; called by muse, mutect2, varscan2
- MAFB | c.*762C>T | 3'UTR (SNP) | VAF 37/767 reads (5%) | called by muse, mutect2
- REXO1L1P | chr8:85663122 G>A | 5'Flank (SNP) | VAF 78/1674 reads (5%) | catalogued as rs1342510569; called by muse, mutect2
- SREBF2 | c.-116C>T | 5'UTR (SNP) | VAF 74/225 reads (33%) | catalogued as rs1194105462; called by muse, mutect2, varscan2
- SYNE2 | c.17871+277C>T | Intron (SNP) | VAF 66/323 reads (20%) | called by muse, mutect2, varscan2
- ZNF812P | n.977G>T | RNA (SNP) | VAF 139/318 reads (44%) | called by muse, mutect2, varscan2
